Somatic mutation profile of tumor specimen ER-ACGR-TTP1-A (aliquot ER-ACGR-TTP1-A-1-0-D-A49N-34) from EXCEPTIONAL_RESPONDERS case ER-ACGR, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 52.1 years (19,015 days).
Specimen ER-ACGR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a44b0be-392f-44fa-84a1-1b8a59216628.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-ACGR-NB1-A (Blood Derived Normal), aliquot ER-ACGR-NB1-A-1-0-D-A49N-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b06538ce-f93e-4a4e-9a30-0667f88c0292

The open-access MAF lists 40 somatic variants for this specimen: 31 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, 3'UTR 5, Nonsense Mutation 3, Silent 3, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 20/134 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BMP5 | c.844A>T p.N282Y | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV63700913; called by muse, mutect2, varscan2
- FGF16 | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV101466331; called by muse, mutect2, varscan2
- LRRC66 | c.1256C>A p.A419E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV58634492; called by mutect2, varscan2
- NBPF14 | c.2615A>G p.E872G | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1430421905; called by muse, varscan2
- ZNF415 | c.703C>G p.Q235E | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV54703931; called by muse, mutect2, varscan2
- ZNF423 | c.2238C>A p.H746Q (on ENST00000563137 / NM_001379286.1; = p.H738Q on NM_015069.4) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99280183; called by muse, mutect2, varscan2
- ZNF474 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs1298047216; called by muse, mutect2
- ARHGEF1 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2, varscan2
- AUNIP | c.101C>G p.T34S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- COL4A6 | c.147+1G>A p.X49_splice | Splice Site (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- GRIN3A | c.1611C>A p.C537* | Nonsense Mutation (SNP) | VAF 4/43 reads (9%) | called by mutect2, varscan2
- IGSF1 | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- INTS6L | c.395A>T p.N132I | Missense Mutation (SNP) | VAF 16/365 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2
- KLHDC1 | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2
- LCLAT1 | c.466G>T p.V156F | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); called by muse, mutect2
- MBNL1 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2
- MYLK | c.982T>A p.S328T | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.021); called by muse, mutect2
- NUTM2G | c.1678C>A p.P560T | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NUTM2G | c.1679C>A p.P560H | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.275); called by muse, mutect2
- SPEF2 | c.567A>T p.R189S | Missense Mutation (SNP) | VAF 14/259 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2
- SSH1 | c.1679G>T p.G560V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- THRA | c.1140C>A p.Y380* | Nonsense Mutation (SNP) | VAF 17/183 reads (9%) | called by muse, mutect2
- TNRC6B | c.164C>A p.P55Q | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2
- TTN | c.82778C>A p.P27593Q (on ENST00000591111; = p.P20169Q on NM_003319.4) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | PolyPhen probably damaging (0.925); called by muse, mutect2
- TTN | c.56458C>A p.L18820I (on ENST00000591111; = p.L11396I on NM_003319.4) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | PolyPhen benign (0.038); called by muse, mutect2, varscan2
- VIRMA | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR87 | c.3851G>T p.W1284L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ZDHHC14 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.266); called by muse, mutect2
- ZNF341 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- CYTH2 | c.1086G>A p.E362= (on ENST00000427476; = p.E361= on NM_004228.7) | Silent (SNP) | VAF 4/42 reads (10%) | called by mutect2, varscan2
- SOAT2 | c.1173C>T p.Y391= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs962793439; called by mutect2, varscan2
- ZNF10 | c.180A>G p.P60= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs886075930; called by muse, mutect2, varscan2
- ACKR2 | c.*1496G>A | 3'UTR (SNP) | VAF 6/36 reads (17%) | catalogued as rs1460342556, COSV56178674; called by muse, varscan2
- CXCR2 | c.*357G>T | 3'UTR (SNP) | VAF 14/176 reads (8%) | called by muse, mutect2
- OPA1 | c.2983+131T>C | Intron (SNP) | VAF 4/22 reads (18%) | catalogued as rs990077966, COSV62483235; called by muse, varscan2
- SPRY3 | c.*451C>A | 3'UTR (SNP) | VAF 6/96 reads (6%) | catalogued as rs1301088531; called by muse, mutect2
- TRIM13 | c.*595T>C | 3'UTR (SNP) | VAF 4/25 reads (16%) | called by mutect2, varscan2
- WDR33 | c.*2451A>G | 3'UTR (SNP) | VAF 9/54 reads (17%) | catalogued as COSV59256339; called by muse, mutect2
